Somatic mutation profile of tumor specimen MP2PRT-PATANL-TMP1-A (aliquot MP2PRT-PATANL-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATANL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,465 days).
Specimen MP2PRT-PATANL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d3686f0-4343-463b-90e3-780162dfce28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATANL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATANL-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/730bb81d-a125-48de-9857-11bc8f6a283c

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, Frame Shift Ins 3, Nonsense Mutation 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.2526delinsCC p.Q842Hfs*128 | Frame Shift Ins (INS) | VAF 163/650 reads (25%) | catalogued as COSV52112986; called by mutect2*, pindel, varscan2*
- CRISPLD2 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 85/249 reads (34%) | catalogued as rs377586344; called by muse, mutect2, varscan2
- ENTPD2 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 275/897 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs563908073, COSV57075830; called by muse, mutect2, varscan2
- MAGEA12 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 127/578 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV63295460; called by muse, mutect2, varscan2
- MYOZ2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 124/423 reads (29%) | catalogued as rs374655743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR6X1 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 105/403 reads (26%) | catalogued as rs143796976; called by muse, mutect2, varscan2
- OTOF | c.3502_3503insGGGGGGGTGC p.Q1168Rfs*12 (on ENST00000272371 / NM_194248.3; = p.Q421Rfs*12 on NM_004802.4) | Frame Shift Ins (INS) | VAF 138/392 reads (35%) | catalogued as COSV55508951; called by mutect2, varscan2
- TP53 | c.847_848insCCCGGC p.R282_R283insPR | In Frame Ins (INS) | VAF 171/253 reads (68%) | catalogued as COSV53297573, COSV99037230; called by mutect2, pindel, varscan2
- CREBBP | c.2527dup p.L843Pfs*127 | Frame Shift Ins (INS) | VAF 137/424 reads (32%) | called by mutect2, varscan2
- HPS1 | c.1296G>T p.M432I | Missense Mutation (SNP) | VAF 188/627 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- REG3A | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- CLCA4 | c.384C>T p.G128= | Silent (SNP) | VAF 64/213 reads (30%) | catalogued as rs377168071; called by muse, mutect2, varscan2
- CXCR3 | c.123G>A p.P41= | Silent (SNP) | VAF 194/918 reads (21%) | catalogued as rs749978310; called by muse, mutect2, varscan2
- MYO9B | c.1500A>G p.A500= | Silent (SNP) | VAF 127/346 reads (37%) | catalogued as rs1250330095; called by muse, mutect2, varscan2
- NTM | c.327C>T p.D109= | Silent (SNP) | VAF 209/642 reads (33%) | catalogued as rs753385528, COSV66177926, COSV66183887; called by muse, mutect2, varscan2
